Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7103, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7103-01A (Primary Tumor).

[page 1 of 2]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) PARTIAL GLOSSECTOMY, LATERAL TONGUE:
DEEPLY INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED.
Focal moderate dysplasia at medial/anterior aspect of surgical margin.
Remaining surgical margins free.
- (B) ANTERIOR MEDIAL MARGIN:
Minor salivary gland and skeletal muscle, no tumor present.
- (C) JUGULAR CHAIN LYMPH NODE, LEVELS II, III AND IV:
METASTATIC SQUAMOUS CARCINOMA IN 1 OF 3 LYMPH NODES FROM LEVEL II.
METASTATIC SQUAMOUS CARCINOMA IN 1 OF 3 LYMPH NODES FROM LEVEL III.
Two lymph nodes from level IV, no tumor present.
- (D) SUBMANDIBULAR GLAND AND LEVEL I LYMPH NODE:
Four lymph nodes from level I, no tumor present.
Salivary gland, no tumor present.
- (E) ADDITIONAL LEVEL IV:
Two lymph nodes, no tumor present.
- (F) POSTERIOR HARD PALATE:
Oral melanotic macule.
- (G) TEETH:
Teeth, gross only.

Entire report and diagnosis completed by: [REDACTED]

GROSS DESCRIPTION

(A) PARTIAL GLOSSECTOMY, LATERAL TONGUE - A partial glossectomy with an overall measurement of 8.0 x 3.8 x 2.0 cm. An ulcerated contracted and slightly raised light-tan and firm lesion (2.0 x 1.0 x 0.6 cm). The tumor is surrounded by normal mucosa and is about 0.8 cm from the deep margin of resection. The specimen is submitted entirely from anterior to posterior as follows.

SECTION CODE: A1-A9, margins of resection; A10-A18, sequential sections of the normal and tumor from anterior to superior. [REDACTED]

*FS/DX: FOCAL MODERATE DYSPLASIA AT MEDIAL/ANTERIOR ASPECT, OTHER FOCAL AREAS DENUDED, REMAINING FREE (GILCREASE). [REDACTED]

(B) PATIENT'S ANTERIOR MEDIAL MARGIN - A pink-tan tissue fragment (2.1 x 1.0 x 0.3 cm).

INK CODE: Blue - anterior.

SECTION CODE: B, submitted in toto for frozen section. [REDACTED]

Page 1 of 2

History Case Pathology Report

File under: Pathology

History Case Pathology

[page 2 of 2]
*FS/DX: MINOR SALIVARY GLAND, NO TUMOR PRESENT. [REDACTED]

(C) JUGULAR CHAIN LYMPH NODE LEVEL II, III, IV (SUTURE AT LEVEL II) - An irregular, pink-red soft tissue fragment (10.0 x 3.2 x 0.8 cm) which is oriented by the surgeon. A level III, IV and V on the report corresponding to the traditional level II, III, and IV respectively. Breast suture is marking the lymph node at level II. Multiple lymph nodes vary in size from 0.4 cm to 1.5 cm respectively. Some lymph nodes are firm. Lymph nodes are submitted in six cassettes.

SECTION CODE: C1, C2, lymph nodes level III corresponding to traditional level II. C1, two lymph nodes; C2, one lymph node bisected; C3-C5, lymph nodes from level IV (corresponding to traditional level III) with C3 and C4, one lymph node bisected; C5, two lymph nodes; C6, two lymph nodes from level V (corresponding to level IV for traditional level IV). [REDACTED]

(D) SUBMANDIBULAR GLAND AND LEVEL I LYMPH NODE, SUTURE ON FASCIA OF LYMPHATIC - An irregular, pink-red soft tissue fragment (9.0 x 3.5 x 2.5 cm) with a submandibular salivary gland (5.0 x 2.5 x 2.3 cm). A black surgical suture is present marking the facial lymphatic chain.

The submandibular salivary gland is grossly unremarkable. Four lymph nodes are dissected from the perisalivary gland. The lymph nodes vary in size from 0.4 cm to 0.8 cm in greatest diameter. They are grossly unremarkable.

SECTION CODE: Representative sections are submitted in four cassettes: D1-D2, representative sections of salivary gland; D3, three lymph nodes; D4, one lymph node. [REDACTED]

*FS/DX: MINOR SALIVARY GLAND, NO TUMOR PRESENT. [REDACTED]

(E) ADDITIONAL LEVEL IV - An irregular, yellow-pink soft tissue fragment (2.5 x 2.0 x 0.3 cm). No invasive lymph node identified. Specimen submitted entirely in two cassettes E1 and E2. [REDACTED]

(F) POSTERIOR HARD PALATE - A single fragment of pale tan tissue (0.2 cm in greatest dimension). Submitted in F. [REDACTED]

(G) TEETH - Multiple teeth and fragments of teeth (5.5 x 5.0 x 3.5 cm in aggregate). The specimen is for gross identification only. [REDACTED]

SNOMED CODES

T-53000 T-C4100

Source: NCI Genomic Data Commons file ae6873ed-f4bb-4a2a-910f-62ae9c5030f5 (TCGA-CV-7103.DA0635C4-493B-4D58-905A-CB5E82C19B59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).